Somatic mutation profile of tumor specimen TCGA-14-0789-01A (aliquot TCGA-14-0789-01A-01D-1492-08) from TCGA case TCGA-14-0789, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 54.9 years (20,050 days).
Specimen TCGA-14-0789-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 97f1ebaf-e1be-4c38-a4ed-0a6a1de62bb1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-14-0789-10A (Blood Derived Normal), aliquot TCGA-14-0789-10A-01D-1492-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7296556a-d904-4a9f-a863-040e36379fb1

The open-access MAF lists 74 somatic variants for this specimen: 50 protein-altering or splice-affecting, 22 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 40, Silent 22, Nonsense Mutation 5, In Frame Del 2, Frame Shift Del 1, Splice Site 1, RNA 1, 5'Flank 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NF1 | c.2848C>T p.Q950* | Nonsense Mutation (SNP) | VAF 53/196 reads (27%) | catalogued as rs1060500357, CM154908, COSV62201077; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACTL9 | c.1231G>A p.V411M | Missense Mutation (SNP) | VAF 55/317 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs782060616, COSV61005266; called by muse, mutect2, varscan2
- AKT1 | c.632C>T p.T211I | Missense Mutation (SNP) | VAF 36/141 reads (26%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.972); catalogued as COSV62572258; called by muse, mutect2, varscan2
- ASB15 | c.998A>G p.D333G | Missense Mutation (SNP) | VAF 64/309 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51929596; called by muse, mutect2, varscan2
- AZGP1 | c.80G>A p.R27H | Missense Mutation (SNP) | VAF 32/163 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs1335547800, COSV52799667; called by muse, mutect2, varscan2
- CACNA2D3 | c.2320G>A p.A774T | Missense Mutation (SNP) | VAF 50/205 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.812); catalogued as rs775275975, COSV55510818; called by muse, mutect2, varscan2
- CALN1 | c.569G>A p.R190Q (on ENST00000329008 / NM_001017440.3; = p.R232Q on NM_031468.4) | Missense Mutation (SNP) | VAF 32/158 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs767122514, COSV61147636; called by muse, mutect2, varscan2
- CCDC158 | c.742G>A p.E248K | Missense Mutation (SNP) | VAF 34/134 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.84); catalogued as COSV66357296; called by muse, mutect2, varscan2
- CHD5 | c.3484G>T p.A1162S | Missense Mutation (SNP) | VAF 33/118 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as COSV52426017; called by muse, mutect2, varscan2
- CHL1 | c.1531A>T p.I511F (on ENST00000397491 / NM_001253387.1; = p.I527F on NM_006614.4) | Missense Mutation (SNP) | VAF 34/136 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV56607695; called by muse, mutect2, varscan2
- CIT | c.5422G>A p.G1808R | Missense Mutation (SNP) | VAF 26/97 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55884446; called by muse, mutect2, varscan2
- CRNN | c.377C>T p.A126V | Missense Mutation (SNP) | VAF 159/646 reads (25%) | SIFT tolerated (0.46); PolyPhen benign (0.005); catalogued as rs774952004, COSV55120594; called by muse, mutect2, varscan2
- EGFR | c.1883G>A p.C628Y | Missense Mutation (SNP) | VAF 94/1020 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV51840469, COSV51851464; called by muse, mutect2
- FGA | c.1284C>A p.Y428* | Nonsense Mutation (SNP) | VAF 106/479 reads (22%) | catalogued as COSV57401687; called by muse, mutect2, varscan2
- FLG2 | c.1166A>C p.Q389P | Missense Mutation (SNP) | VAF 54/199 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.315); catalogued as COSV66173898; called by muse, mutect2, varscan2
- GPRC6A | c.779G>A p.R260Q | Missense Mutation (SNP) | VAF 39/168 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs368860950, COSV59956215; called by muse, mutect2, varscan2
- GPSM2 | c.1955G>C p.R652T | Missense Mutation (SNP) | VAF 38/156 reads (24%) | SIFT tolerated (0.44); PolyPhen benign (0.253); catalogued as COSV51440771, COSV51444810; called by muse, mutect2, varscan2
- GRM3 | c.547C>T p.R183C | Missense Mutation (SNP) | VAF 106/430 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64467183, COSV64474717; called by muse, mutect2, varscan2
- HARS1 | c.1469G>A p.R490Q | Missense Mutation (SNP) | VAF 19/108 reads (18%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs1295541335, COSV56909238; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HHIPL2 | c.1309C>T p.R437* | Nonsense Mutation (SNP) | VAF 57/199 reads (29%) | catalogued as rs778287202, COSV58565046; called by muse, varscan2
- HPCAL4 | c.193G>A p.A65T | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.794); catalogued as COSV65716398; called by muse, mutect2, varscan2
- ITPR3 | c.1420C>T p.Q474* | Nonsense Mutation (SNP) | VAF 26/114 reads (23%) | catalogued as COSV65415278; called by muse, mutect2, varscan2
- LDLR | c.1514G>C p.G505A | Missense Mutation (SNP) | VAF 32/191 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.878); catalogued as CM023641, COSV52946222; called by muse, mutect2, varscan2
- LPA | c.3287+1G>A p.X1096_splice | Splice Site (SNP) | VAF 169/771 reads (22%) | catalogued as rs767906902, COSV60309190; called by muse, mutect2, varscan2
- LRP1B | c.12446A>G p.E4149G | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT tolerated (0.22); PolyPhen benign (0.046); catalogued as COSV67278893; called by muse, mutect2, varscan2
- NCOA5 | c.250G>A p.V84M | Missense Mutation (SNP) | VAF 66/229 reads (29%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as rs777887637, COSV51645044; called by muse, mutect2, varscan2
- OR52D1 | c.286T>A p.S96T | Missense Mutation (SNP) | VAF 53/199 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0.026); catalogued as COSV59488427; called by muse, mutect2, varscan2
- OTUD7A | c.1547G>A p.R516H (on ENST00000307050 / NM_001382637.1; = p.R509H on NM_130901.3) | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61043815; called by muse, mutect2, varscan2
- PAN3 | c.995C>T p.A332V | Missense Mutation (SNP) | VAF 110/388 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.036); catalogued as rs775770672, COSV66707094; called by muse, mutect2, varscan2
- PCDHB4 | c.1891G>A p.E631K | Missense Mutation (SNP) | VAF 43/161 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.952); catalogued as rs781879874, COSV52027450; called by muse, mutect2, varscan2
- PIK3CB | c.1660G>A p.E554K | Missense Mutation (SNP) | VAF 56/189 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as COSV56690646; called by muse, mutect2, varscan2
- PLB1 | c.574G>A p.G192S | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT tolerated (0.43); PolyPhen benign (0.007); catalogued as rs149462466; called by muse, mutect2, varscan2
- POF1B | c.133A>C p.K45Q | Missense Mutation (SNP) | VAF 28/58 reads (48%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.22); catalogued as COSV53135663; called by muse, mutect2, varscan2
- PRIMA1 | c.295G>A p.V99I | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.801); catalogued as rs200260569, COSV60264799, COSV60265016; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PTPRA | c.709G>A p.D237N | Missense Mutation (SNP) | VAF 35/144 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.196); catalogued as rs773334274, COSV53780647; called by muse, mutect2, varscan2
- RYR2 | c.7027C>T p.L2343F | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63705227, COSV63717015; called by muse, mutect2, varscan2
- RYR3 | c.106T>A p.F36I | Missense Mutation (SNP) | VAF 53/218 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.03); catalogued as COSV66809676; called by muse, mutect2, varscan2
- SGO2 | c.2905G>A p.E969K | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0.057); catalogued as COSV63418414; called by muse, mutect2, varscan2
- SP140 | c.643A>T p.S215C | Missense Mutation (SNP) | VAF 25/110 reads (23%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.887); catalogued as COSV59454477; called by muse, mutect2, varscan2
- SRRM4 | c.620G>A p.R207H | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.838); catalogued as rs532719039, COSV57423555; called by muse, mutect2, varscan2
- THBS4 | c.2863A>G p.N955D | Missense Mutation (SNP) | VAF 41/165 reads (25%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as COSV63471106; called by muse, mutect2, varscan2
- TLR10 | c.152C>T p.T51M | Missense Mutation (SNP) | VAF 36/142 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as rs375480992; called by muse, mutect2, varscan2
- VEGFA | c.433C>T p.R145* (on ENST00000523873 / NM_001171623.1; = p.R325* on NM_003376.6) | Nonsense Mutation (SNP) | VAF 45/179 reads (25%) | catalogued as rs45533131, CM119370, COSV57879341; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ZNF697 | c.1489G>A p.E497K | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); catalogued as rs1391287594, COSV70284066; called by muse, mutect2, varscan2
- ZP2 | c.1246C>T p.R416W | Missense Mutation (SNP) | VAF 26/114 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.096); catalogued as rs766836952, COSV54817102; called by muse, mutect2, varscan2
- ZRSR2 | c.1055G>A p.R352Q | Missense Mutation (SNP) | VAF 51/104 reads (49%) | SIFT tolerated (0.15); PolyPhen benign (0.216); catalogued as COSV57067781; called by muse, mutect2, varscan2
- RAD51AP2 | c.741del p.K247Nfs*11 | Frame Shift Del (DEL) | VAF 36/154 reads (23%) | called by mutect2, pindel, varscan2
- STAG2 | c.442dup p.M148Nfs*3 | Frame Shift Ins (INS) | VAF 32/80 reads (40%) | called by mutect2, pindel, varscan2
- THOC2 | c.4332_4334del p.P1446del | In Frame Del (DEL) | VAF 26/56 reads (46%) | called by pindel, varscan2
- ZNF546 | c.2479_2481del p.H827del | In Frame Del (DEL) | VAF 20/98 reads (20%) | called by mutect2, pindel, varscan2
- ABCB4 | c.216C>A p.P72= | Silent (SNP) | VAF 23/120 reads (19%) | catalogued as rs746750803, COSV55942367; called by muse, mutect2, varscan2
- ACVRL1 | c.1152G>A p.Q384= | Silent (SNP) | VAF 46/171 reads (27%) | catalogued as COSV66361246; called by muse, mutect2, varscan2
- DBH | c.639C>T p.T213= | Silent (SNP) | VAF 20/82 reads (24%) | catalogued as COSV55042495, COSV99708017; called by muse, mutect2, varscan2
- ESPL1 | c.6300C>T p.P2100= | Silent (SNP) | VAF 20/101 reads (20%) | catalogued as COSV54477209; called by muse, mutect2, varscan2
- GABRB3 | c.1200C>A p.I400= | Silent (SNP) | VAF 57/224 reads (25%) | catalogued as COSV54683557, COSV54685401; called by muse, mutect2, varscan2
- GIPC1 | c.339G>C p.L113= | Silent (SNP) | VAF 55/324 reads (17%) | catalogued as COSV61775127; called by muse, mutect2, varscan2
- HMCN1 | c.8814C>A p.I2938= | Silent (SNP) | VAF 16/46 reads (35%) | catalogued as COSV54944881; called by muse, mutect2
- LINGO4 | c.786C>T p.C262= | Silent (SNP) | VAF 50/199 reads (25%) | catalogued as rs769036572, COSV63216824; called by muse, mutect2, varscan2
- MRTO4 | c.477C>T p.P159= | Silent (SNP) | VAF 29/138 reads (21%) | catalogued as rs1238626382, COSV57673190, COSV57674725; called by muse, mutect2, varscan2
- OLFML2A | c.924C>T p.N308= | Silent (SNP) | VAF 21/77 reads (27%) | catalogued as rs954475093, COSV56585855; called by muse, mutect2, varscan2
- PCDHA2 | c.201G>A p.A67= | Silent (SNP) | VAF 88/337 reads (26%) | catalogued as rs782585524, COSV65371264; called by muse, mutect2, varscan2
- PDE4DIP | c.3030G>A p.R1010= | Silent (SNP) | VAF 44/190 reads (23%) | catalogued as rs782507477, COSV57699079, COSV57731045; called by muse, mutect2, varscan2
- PRMT3 | c.987G>A p.E329= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as COSV58181161; called by muse, mutect2, varscan2
- PRRT1 | c.543C>T p.V181= | Silent (SNP) | VAF 20/90 reads (22%) | catalogued as rs947118282, COSV52999707; called by muse, mutect2, varscan2
- S100A7A | c.102G>A p.T34= | Silent (SNP) | VAF 58/285 reads (20%) | catalogued as rs370692845; called by muse, mutect2, varscan2
- TLR7 | c.654C>T p.A218= | Silent (SNP) | VAF 31/71 reads (44%) | catalogued as rs201282415, COSV101027829, COSV66124680; called by muse, mutect2, varscan2
- TMPRSS4 | c.1038G>A p.A346= | Silent (SNP) | VAF 8/29 reads (28%) | catalogued as rs764161015, COSV71109553; called by muse, mutect2, varscan2
- TRIP11 | c.3639G>A p.K1213= | Silent (SNP) | VAF 36/146 reads (25%) | catalogued as COSV50966098, COSV50973458; called by muse, mutect2, varscan2
- TSKS | c.1653C>T p.H551= | Silent (SNP) | VAF 51/278 reads (18%) | catalogued as COSV55879857, COSV99883537; called by muse, mutect2, varscan2
- UGT1A10 | c.27C>T p.P9= | Silent (SNP) | VAF 42/172 reads (24%) | catalogued as rs1322999911, COSV60853075; called by muse, mutect2, varscan2
- ZNF516 | c.675C>T p.T225= | Silent (SNP) | VAF 17/70 reads (24%) | catalogued as rs1461012531, COSV71587325; called by muse, mutect2, varscan2
- ZNF532 | c.2235C>T p.D745= | Silent (SNP) | VAF 20/83 reads (24%) | catalogued as COSV60175998; called by muse, mutect2, varscan2
- C12orf77 | n.432G>A | RNA (SNP) | VAF 25/86 reads (29%) | catalogued as rs768542299; called by muse, mutect2, varscan2
- MATN4 | chr20:45308174 C>A | 5'Flank (SNP) | VAF 39/172 reads (23%) | catalogued as COSV59215982; called by muse, mutect2, varscan2
